CCDI case PBBVWS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/d1bf8ed3-57e9-4e9f-897e-1e6879b54dd0

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pleomorphic rhabdomyosarcoma, adult type: ICD-O-3 morphology code: 8901/3; Tissue or organ of origin: Short bones of upper limb and associated joints; Age at diagnosis: 20.2 years (7,395 days).

Biospecimens (2 samples)
- Sample 0DJE39: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJE3G: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
